Somatic mutation profile of tumor specimen TCGA-J4-A6M7-01A (aliquot TCGA-J4-A6M7-01A-11D-A31L-08) from TCGA case TCGA-J4-A6M7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.8 years (19,640 days).
Specimen TCGA-J4-A6M7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7c810ce-9092-459f-975f-3979533ac46e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A6M7-10A (Blood Derived Normal), aliquot TCGA-J4-A6M7-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd52ec45-06b3-4040-894f-0667053d7406

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 9, Silent 8, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757293052, COSV63928785; called by muse, mutect2, varscan2
- CCT8L2 | c.1460A>T p.N487I | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63462404; called by muse, mutect2, varscan2
- GRID2 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV56204572; called by muse, mutect2, varscan2
- LRIG2 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs371835362; called by muse, mutect2, varscan2
- OTOF | c.3401G>A p.R1134Q (on ENST00000272371 / NM_194248.3; = p.R387Q on NM_004802.4) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs397517943, COSV55502769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE1B | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54492652; called by muse, mutect2
- PNPLA4 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66854066; called by muse, mutect2, varscan2
- PTPRC | c.3311T>C p.F1104S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61411467; called by muse, mutect2, varscan2
- VAV2 | c.177C>A p.D59E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV64081861; called by muse, mutect2, varscan2
- OR52D1 | c.751_752insC p.I251Tfs*32 | Frame Shift Ins (INS) | VAF 14/112 reads (13%) | called by mutect2, pindel*
- CACNB2 | c.27G>T p.S9= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as rs777800740, COSV56611284, COSV56623598; called by muse, mutect2, varscan2
- CLPSL1 | c.183C>T p.C61= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1172165041, COSV65814747, COSV65814886; called by muse, mutect2, varscan2
- CNTNAP1 | c.2199C>T p.D733= | Silent (SNP) | VAF 72/200 reads (36%) | catalogued as rs144310425, COSV52849439; called by muse, mutect2, varscan2
- KCNJ4 | c.1083G>C p.L361= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV57856202, COSV57857075; called by muse, mutect2
- MC3R | c.21G>T p.L7= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as COSV54762897; called by muse, mutect2, varscan2
- RYR3 | c.273C>T p.G91= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs375622890; called by muse, mutect2, varscan2
- TAB2 | c.1218A>G p.T406= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV53852491; called by muse, mutect2, varscan2
- TBX5 | c.72C>T p.C24= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs746284842, COSV59859380; called by muse, mutect2, varscan2
